Surgical pathology report (de-identified scan), TCGA case TCGA-VN-A88N, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-VN-A88N-01A (Primary Tumor).

[page 1 of 5]
Gender: Male	Birth Date:	Admit Date:
Attending:	Admit Protocol:	Age
		Location:

Surgical Pathology	Final Results
--------------------	---------------

Surgical Pathology
CASE NUMBER:
DIAGNOSIS:

Final

- Prostate:
- Adenocarcinoma, Gleason score 7 (4+3) involving 30% of the right and 10% of the left lobe.
- Perineural invasion present.
- No capsular or seminal vesicle invasion seen.
- Inked margins of resection are free of tumor.
- Prostatic glandular atrophy.
- Lymph node, fat and lymph node anterior to prostate: Fibroadipose tissue. No tumor seen.
- Lymph node, left obturator, excision: Lymph nodes (0/13). No tumor seen.
- Lymph node, right obturator lymph node packet, excision: Lymph nodes (0/19). No tumor seen.
- Lymph node, left external iliac, excision: Lymph nodes (0/6). No tumor seen.
- Lymph node, right external iliac, excision: Lymph nodes (0/12). No tumor seen.

ICD-O-3
Adenocarcinoma, acinar
path 8140/3
Adenocarcinoma NOS
8140/3
Site: Prostate NOS
C61.9
10/7/13

NOTE:

CAP Cancer Protocol:
PROSTATE GLAND: Radical Prostatectomy

Procedure
Radical prostatectomy
Prostate Size
Weight: 30.6 g
Size: 4.6 x 4.0 x 2.9 cm

Lymph Node Sampling
Pelvic lymph node dissection

Histologic Type
Adenocarcinoma (acinar, not otherwise specified)
Histologic Grade (Note B)
Gleason Pattern

Primary Pattern
Grade 4

Secondary Pattern
Grade 3

Total Gleason Score: 7

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

Requested By:

Do not file in Medical Record

[page 2 of 5]
Gender: Male	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Age:
		Location:

Surgical Pathology	Final Results
---------------------------	----------------------

Tumor Quantitation
Proportion (percentage) of prostate involved by tumor: 40%

Extraprostatic Extension
Not identified

Seminal Vesicle Invasion (invasion of muscular wall required)
Not identified

Margins
Margins uninvolved by invasive carcinoma

Treatment Effect on Carcinoma
Not identified

Lymph-Vascular Invasion
Not identified
+ Perineural Invasion
+ Present

Pathologic Staging (pTNM)
Primary Tumor (pT)
+ pT2c: Bilateral disease
Regional Lymph Nodes (pN)
pN0: No regional lymph node metastasis

Number of Lymph Nodes Examined
Specify: 50

Number of Lymph Nodes Involved
Specify: 0
Distant Metastasis (pM)
Not applicable

+ Additional Pathologic Findings
+ Other (specify): Prostatic glandular atrophy.

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by [redacted] they have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Brief Clinical History: M with G4+3 CaP
Specimen Taken For Protocol:
Yes Allocate Order to Protocol:

PROCEDURE: Operative Findings: see dictation Post-Operative
Diagnosis: prostate

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

Requested By:

Do not file in Medical Record

[page 3 of 5]
Gender: Male	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Age:
		Location:

Surgical Pathology

Final Results

cancer Pre-Operative Diagnosis: prostate cancer

- SPECIMENS SUBMITTED: 1. PROSTATE
2. LYMPH NODES, Fat anterior to prostate
3. OBTURATOR LYMPH NODE(S), Left
4. OBTURATOR LYMPH NODE(S), Right
5. LYMPH NODES, Left external iliac
6. LYMPH NODES, Right external iliac

GROSS DESCRIPTION:

- Prostate: Consists of a prostatectomy specimen weighing 30.6 grams with the following measurements:
Left-right: 4.6 cm
Anterior-posterior: 2.9 cm
Apex-base: 4.0 cm
Left seminal vesicle: 2.5 x 1.0 x 0.5 cm
Left vas deferens: 4.2 cm in length, 0.6 cm in diameter
Right seminal vesicle: 2.5 x 6.9 x 0.6 cm
Right vas deferens: 3.5 cm in length, 0.6 cm in diameter
The prostate is inked as follows: Urethra in yellow, anterior one-third in black, right posterior two-thirds in blue, and left posterior two-thirds in red. Gross photographs are taken. One cut is made revealing a tan nodular cut surface and hard to yellow area measuring 0.9 cm in greatest dimension. Approximately 0.8 x 0.5 x 0.3 cm of tumor from the right apex and approximately 0.8 x 0.6 x 0.3 cm of normal-appearing prostatic tissue from the left apex are procured for the The measurement was documented and performed by and Received in Pathology is a specimen matching the above description. The prostate is serially sectioned from apex to base using a custom fabricated mold. Summary of sections is as follows:
Cassettes -F: Serially sectioned prostate from apex to base entirely submitted.
Cassettes -H: Proximal right and left seminal vesicles and vas deferens.
Cassettes J: Distal left seminal vesicle and vas deferens entirely submitted.
Cassettes : Distal right seminal vesicle and vas deferens entirely submitted.
- "Fat and lymph node anterior to prostate" consists of 2 yellow-tan soft tissue fragments measuring 3 cm in aggregate. The tissue is palpated for candidate lymph nodes. After palpation, no candidate lymph nodes are found and the tissue is entirely submitted in a white cassette labeled 2B.
- "Left obturator lymph node" consists of a yellow-tan soft tissue fragment measuring 4 x 2 x 1.4 cm. The tissue fragment is palpated for candidate lymph nodes. Six candidate lymph nodes are

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

Requested By:

Do not file in Medical Record

[page 4 of 5]
Gender: Male		Birth Date:	Admit Protocol:
Admit Protocol:		Admit Protocol:	Age:
			Location:

Surgical Pathology	Final Results
---------------------------	----------------------

identified, 4 minute candidate lymph nodes are placed in a white cassette labeled . Another candidate node is bisected revealing yellow surface and is placed entirely in a white cassette labeled . B, and another candidate lymph node is bisected revealing yellow surface and is placed entirely in a white cassette labeled . The remainder of the tissue is placed in white cassettes labeled . D and 3E.

4. "Right obturator lymph node packet" consists of several fibrofatty yellow-tan soft tissue fragments measuring in aggregate 3.7 x 3 x 1.5 cm. The fragments are palpated for candidate lymph nodes and 12 candidate lymph nodes are found measuring in size from minute to 2 cm. Five minute to 0.5 cm candidate lymph nodes are placed in a white cassette labeled . Other 5 small candidate lymph nodes ranging from minute to 0.5 cm are placed in another white cassette labeled . A larger candidate node measuring 3 cm in length is placed in a white cassette labeled . The remainder of the fibroadipose tissue is placed in white cassettes labeled . D and 4E.

5. "Left external iliac lymph node" consists of 2 yellow-tan soft tissue fragments measuring in aggregate 3.5 x 2.5 x 1.2 cm. The tissue is palpated for candidate lymph nodes and 2 candidate lymph nodes are found. The larger candidate node measures 2.5 cm in length and is sectioned and placed in white cassettes #5A and 5B. A smaller candidate node measuring 0.7 cm in length is also bisected and placed in a white cassette labeled #5C. The remainder of the fibrofatty tissue is placed in a white cassette labeled .

6. "Right external lymph node" consists of multiple soft tissue fragments measuring in aggregate 4 x 2.5 x 2 cm. The tissue is palpated for candidate lymph nodes and 8 candidate lymph nodes are found. Seven candidate lymph nodes of similar size are placed in cassette . Node measuring 1.7 cm in length is bisected and placed in a white cassette labeled . B. Larger candidate node measuring 2 x 1.2 x 0.6 cm is bisected and entirely placed in a white cassette labeled . The remainder of the specimen is placed in white cassettes labeled . D and 6E.

Gross Description dictated by
Description dictated by .

Additional Gross

No consultants
Accessioned:
Final Report Signed Out:

<Resident Signature>

[page 5 of 5]
Gender: Male

Birth Date:

Admit Protocol:

Age:

Admit Protocol:

Admit Protocol:

Location:

Surgical Pathology

Final Results

<Sign Out Dr. Signature>

Date Report Signed:

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

Requested By:

Do not file in Medical Record

Source: NCI Genomic Data Commons file 974455d6-2cbd-4e29-a3fb-7bd62ec5a4b8 (TCGA-VN-A88N.CB3E6129-CCCC-4EEB-88CD-63DE78D8F163.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).